Surgical pathology report (de-identified scan), TCGA case TCGA-49-AARO, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AARO-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, LEFT UPPER LOBE (LOBECTOMY): INFILTRATING POORLY DIFFERENTIATED ADENOCARCINOMA OF THE LUNG (2.5 CM) WITH PAPILLARY FEATURES. THE TUMOR IS ADJACENT TO, BUT DOES NOT INVADE THROUGH THE VISCERAL PLEURA. THE ADJACENT LUNG SHOWS CENTRILOBULAR EMPHYSEMA AND SEVERAL FOCI OF ATYPICAL ALVEOLAR HYPERPLASIA. ALL SURGICAL MARGINS (BRONCHIAL, VASCULAR AND STAPLED PARENCHYMAL MARGIN) ARE NEGATIVE FOR TUMOR. THE PATHOLOGIC STAGE IS T1N0MX. SEE NOTE.

NOTE: This case was shown at the

2. STATION 5 (DISSECTION): SIX (6) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3. STATION 7 (DISSECTION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

*Electronic signature

=====

Clinical History:
LEFT LUNG MASS.

GROSS DESCRIPTION

(Continued on next page.)

ICD-O.3
Adenocarcinoma, papillary NOS
8260/3
Site: Lung, upper lobe
CB4.1
JVO 5/20/14

[page 2 of 3]
PART #1: LEFT UPPER LOBE
Resident Pathologist:

The specimen is received fresh labeled with the patient's name [REDACTED] and designated as left upper lobe. It consists of a grossly identifiable lobectomy specimen, measuring 18.0 x 8.2 x 3.3 cm and weighing in aggregate 163 gm. In the epical half, on the lateral aspect of the lobe, is a tumor mass, measuring 4.5 cm in greatest dimension. The mass has an irregular infiltrating border and involves the pleural surface, such that the pleura is puckered in the area overlying the tumor. This area of puckering measures 2.5 cm in greatest dimension. The tumor is approximately 0.5 cm from the hilar bronchial margin and appears grossly to involve large branches of the right upper lobe bronchus and blood vessels. On cut section, the tumor is tan-white and gray, marbled in appearance. There are two staple lines on the specimen. The epical staple line measures 4.5 cm in length and the more inferior staple line measures 6.0 cm in length. The tumor approaches to within 0.5 cm of the epical staple line. The staple lines are removed and the lung parenchyma adjacent is inked blue. The pleural surface overlying the tumor has been inked black. The specimen is serially sectioned, revealing no other lesions. Representative sections are submitted.

SUMMARY OF SECTIONS

- 1 - A- M (VASCULAR MARGIN)
- 1 - B- 2 (BRONCHIAL MARGIN)
- 1 - C- M (MULTIPLE POSSIBLE HILAR LYMPH NODES)
- 1 - D- 2 (MULTIPLE POSSIBLE HILAR LYMPH NODES)
- 2 -E&F- M EACH (STAPLE MARGIN, SHAVE)
- 1 - G- 1 (TUMOR VS STAPLE MARGIN)
- 2 -H&I- 1 EACH (TUMOR AT PLEURA)
- 1 - J- 1 (TUMOR INVOLVING SEGMENTAL BRONCHUS)
- 1 - K- 1 (REPRESENTATIVE TUMOR)
- 11-TOTAL-M

(Continued on next page.)

[page 3 of 3]
PART #2: STATION 5
Resident Pathologist:

The specimen is received fresh labeled with the patient's name [REDACTED] and designated as station 5. It consists of one piece of yellow-black soft tissue, measuring 1.5 x 1.0 x 0.5 cm. The specimen is dissected, revealing two possible lymph nodes. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 2 (POSSIBLE LYMPH NODES)
1 - B - M (REMAINING FAT)
2 - TOTAL - M

PART #3: STATION 7
Resident Pathologist:

The specimen is received fresh labeled with the patient's name [REDACTED] and designated as station 7. It consists of one piece of tan-black soft tissue, measuring 1.2 x 0.8 x 0.4 cm. The specimen is bisected and submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 2 (ONE LYMPH NODE)
1 - TOTAL - 2

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file 92b5290a-dd59-4a95-8a7b-116690dd99f9 (TCGA-49-AARO.5E71C822-2014-431A-B050-102C4A845321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).